Somatic mutation profile of tumor specimen TCGA-D8-A1JS-01A (aliquot TCGA-D8-A1JS-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Intraductal papillary adenocarcinoma with invasion; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.1 years (28,178 days).
Specimen TCGA-D8-A1JS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e9201fe-9eee-465f-b40a-5ad2e5ec2931.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JS-10A (Blood Derived Normal), aliquot TCGA-D8-A1JS-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82688585-7a6a-4d64-8172-29eb42c8c181

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 34/64 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC43 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59520386; called by muse, mutect2, varscan2
- E2F1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55776363; called by muse, mutect2, varscan2
- HDAC1 | c.1422-2A>T p.X474_splice | Splice Site (SNP) | VAF 76/163 reads (47%) | catalogued as COSV61481843; called by muse, mutect2, varscan2
- HEATR1 | c.5140G>A p.A1714T | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs367715127; called by muse, mutect2
- ITGB2 | c.1681G>A p.D561N (on ENST00000302347; = p.D537N on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV56612121; called by muse, mutect2, varscan2
- LDLRAD4 | c.99C>A p.N33K | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV63340860; called by muse, mutect2, varscan2
- MUC16 | c.11051G>A p.S3684N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV67452370; called by muse, mutect2, varscan2
- PCGF3 | c.134A>T p.Y45F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV62860292; called by muse, mutect2, varscan2
- SARS1 | c.731A>T p.D244V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52322455; called by muse, mutect2, varscan2
- SFRP5 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV99823276; called by muse, mutect2
- SH3KBP1 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV65643564; called by muse, mutect2, varscan2
- TGS1 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV52702068; called by muse, mutect2, varscan2
- THUMPD3 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61506494; called by muse, mutect2, varscan2
- TRIM17 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV52859264; called by muse, mutect2, varscan2
- CACNA1A | c.4320G>A p.K1440= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs1345559644, COSV64206241; called by muse, mutect2, varscan2
- INTS12 | c.825A>T p.G275= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV60863105; called by muse, mutect2, varscan2
- KIF4A | c.594G>A p.R198= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV65544815; called by muse, mutect2, varscan2
- LOXL2 | c.1611C>T p.Y537= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs778888581, COSV66690471; called by muse, mutect2, varscan2
- MRPS18C | c.6C>T p.A2= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs760876096, COSV55026633; called by muse, mutect2, varscan2
- RPUSD4 | c.681C>T p.D227= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs765293408, COSV53598745; called by muse, mutect2, varscan2
